Somatic mutation profile of tumor specimen TCGA-GV-A3QH-01A (aliquot TCGA-GV-A3QH-01A-11D-A21Z-08) from TCGA case TCGA-GV-A3QH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 67.6 years (24,681 days).
Specimen TCGA-GV-A3QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9792720d-fae3-495f-910c-1370ff61e908.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A3QH-10A (Blood Derived Normal), aliquot TCGA-GV-A3QH-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f40bc04-4c4c-42fd-a6ff-e239b3a90b7a

The open-access MAF lists 178 somatic variants for this specimen: 136 protein-altering or splice-affecting, 41 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 41, Nonsense Mutation 9, Splice Site 8, Frame Shift Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RXRA | c.1280C>A p.S427Y | Missense Mutation (SNP) | VAF 91/138 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 67/87 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.3864C>A p.S1288R | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53994231, COSV99663535; called by muse, mutect2, varscan2
- AMPH | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 157/262 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57745788; called by muse, mutect2, varscan2
- ANGPT4 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as rs150174277, COSV67921961; called by muse, varscan2
- ANO6 | c.2658G>C p.M886I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV57662807, COSV57669960; called by muse, mutect2, varscan2
- ARFGEF1 | c.3221G>A p.R1074Q | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.464); catalogued as COSV51610891; called by muse, varscan2
- ARHGAP29 | c.55C>G p.Q19E | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV53113256; called by muse, mutect2, varscan2
- ARHGAP31 | c.3443C>G p.S1148C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51794734; called by muse, mutect2, varscan2
- ARHGEF10L | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs780508220, COSV63421255; called by muse, mutect2, varscan2
- BCAS3 | c.2135C>T p.S712F (on ENST00000390652 / NM_001353144.2; = p.S697F on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/220 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66776062; called by muse, mutect2, varscan2
- BEST2 | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as rs750474711, COSV50367813; called by muse, mutect2, varscan2
- BMX | c.57G>C p.K19N | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59591852; called by muse, mutect2, varscan2
- BTBD1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs544691434, COSV55601588; called by muse, mutect2, varscan2
- BTBD7 | c.2065C>G p.Q689E | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58287746; called by muse, mutect2, varscan2
- BTN2A2 | c.1405T>C p.Y469H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV61857777; called by muse, mutect2, varscan2
- CADPS | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as rs150415917; called by muse, mutect2, varscan2
- CARM1 | c.1583C>G p.S528C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.241); catalogued as COSV53403864; called by muse, mutect2, varscan2
- CCDC125 | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.528); catalogued as COSV67288266; called by muse, mutect2, varscan2
- CCDC178 | c.1657-1G>C p.X553_splice | Splice Site (SNP) | VAF 16/75 reads (21%) | catalogued as COSV55779275; called by muse, mutect2, varscan2
- CDH11 | c.2235T>G p.Y745* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV51778022; called by muse, mutect2, varscan2
- CDK7 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.466); catalogued as COSV56514005; called by muse, mutect2, varscan2
- CFTR | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.7); catalogued as rs397508378, CM930119, CM970287, COSV50063470; ClinVar: not provided; called by muse, mutect2, varscan2
- CHD4 | c.1579G>A p.E527K (on ENST00000357008 / NM_001363606.2; = p.E540K on NM_001273.5) | Missense Mutation (SNP) | VAF 148/277 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV58903730, COSV58907342; called by muse, mutect2, varscan2
- CHSY3 | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV59279699; called by muse, mutect2, varscan2
- CLASP2 | c.4300A>T p.T1434S (on ENST00000359576; = p.T1433S on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56277487; called by muse, mutect2, varscan2
- CLEC14A | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60562894; called by muse, mutect2, varscan2
- CPED1 | c.2014C>A p.L672M | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60005036; called by muse, mutect2, varscan2
- CSNK1G3 | c.32C>G p.S11* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100631318; called by muse, mutect2, varscan2
- CUL3 | c.637T>C p.S213P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52366084; called by muse, varscan2
- CYP4B1 | c.543C>G p.F181L | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV54724173; called by muse, mutect2, varscan2
- DAAM1 | c.2343G>C p.K781N | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62836368, COSV62837267; called by muse, mutect2, varscan2
- DBT | c.96G>T p.L32F | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.019); catalogued as COSV64495701; called by muse, mutect2, varscan2
- DICER1 | c.4514C>G p.S1505C | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58622405, COSV58623648; called by muse, mutect2, varscan2
- DLL1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1361312021, COSV64537815; called by muse, mutect2, varscan2
- DOP1A | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV52712137; called by muse, mutect2, varscan2
- DPYS | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59827061; called by muse, mutect2, varscan2
- ECM1 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs751774164, COSV60873562; called by muse, mutect2, varscan2
- EIF4G3 | c.3028G>C p.E1010Q | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV51685332; called by muse, mutect2, varscan2
- EPHA2 | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64453505; called by muse, mutect2, varscan2
- ERCC4 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV61312305, COSV61312514; called by muse, mutect2, varscan2
- F5 | c.3886C>G p.P1296A | Missense Mutation (SNP) | VAF 168/360 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV63125247; called by muse, varscan2
- FARP2 | c.3074G>A p.S1025N | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV50873072; called by muse, mutect2, varscan2
- FIG4 | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs754830354, COSV57788504; called by muse, mutect2, varscan2
- FLG2 | c.4799G>A p.G1600D | Missense Mutation (SNP) | VAF 160/304 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV66169657; called by muse, mutect2, varscan2
- FREM2 | c.1244T>A p.V415E | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV54841630; called by muse, mutect2, varscan2
- FRY | c.6899C>T p.P2300L | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66572380; called by muse, mutect2, varscan2
- GALNT12 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1487945747; ClinVar: uncertain significance; called by mutect2, varscan2
- GALNT9 | c.1399G>C p.E467Q (on ENST00000328957 / NM_001122636.2; = p.E101Q on NM_021808.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.974); catalogued as COSV100202232, COSV61100178; called by muse, mutect2, varscan2
- GAS2L2 | c.153C>A p.D51E | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs782333719; called by muse, mutect2, varscan2
- GEN1 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT tolerated (0.95); PolyPhen benign (0.093); catalogued as COSV58057147; called by muse, mutect2, varscan2
- GNS | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.083); catalogued as COSV50695110; called by muse, mutect2, varscan2
- GON7 | c.209-1G>C p.X70_splice | Splice Site (SNP) | VAF 29/63 reads (46%) | catalogued as COSV50149975; called by muse, mutect2, varscan2
- GPR151 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV57038491; called by muse, mutect2, varscan2
- HDAC10 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs139748706; called by muse, mutect2, varscan2
- HYOU1 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV68216161; called by muse, mutect2, varscan2
- IGSF9B | c.3673C>T p.R1225C | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs767068283, COSV58068700, COSV58069177; called by muse, mutect2, varscan2
- INVS | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52443826; called by muse, mutect2, varscan2
- ITGA8 | c.210-1G>C p.X70_splice | Splice Site (SNP) | VAF 43/106 reads (41%) | catalogued as COSV65230576; called by muse, mutect2, varscan2
- KDM6A | c.4009G>A p.E1337K | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65041851, COSV65042113; called by muse, mutect2, varscan2
- KLRC4 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 71/289 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV58672010; called by muse, mutect2, varscan2
- LRP5 | c.1684G>C p.D562H | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53717761; called by muse, mutect2, varscan2
- MBD5 | c.930G>C p.M310I | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV68697957; called by muse, mutect2, varscan2
- MPG | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774213821, COSV54738751; called by muse, mutect2
- MUC16 | c.11134A>G p.T3712A | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as COSV67474514; called by muse, mutect2
- MUC5AC | c.13760C>G p.S4587C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.02); catalogued as COSV64369676; called by muse, mutect2, varscan2
- MYH10 | c.5926G>C p.E1976Q | Missense Mutation (SNP) | VAF 197/280 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.932); catalogued as COSV52603838; called by muse, mutect2, varscan2
- MYLK3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV67364903; called by muse, mutect2, varscan2
- MYO7A | c.1559C>G p.T520R | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV68685197; called by muse, mutect2, varscan2
- NFE2L3 | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV50230578; called by muse, mutect2, varscan2
- NOA1 | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.248); catalogued as COSV51737599; called by muse, mutect2, varscan2
- OAS2 | c.1053C>A p.F351L | Missense Mutation (SNP) | VAF 196/412 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60802929; called by muse, varscan2
- OR4K14 | c.699C>A p.S233R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59293129; called by muse, mutect2, varscan2
- OTOL1 | c.1028C>A p.S343* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as rs375108313; called by muse, mutect2, varscan2
- PARVB | c.634-1G>A p.X212_splice | Splice Site (SNP) | VAF 28/108 reads (26%) | catalogued as COSV58688022; called by muse, mutect2, varscan2
- PCDHA10 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs782707848, COSV56482042; called by muse, varscan2
- PCDHB9 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV53375579, COSV53380716; called by muse, varscan2
- PCDHB9 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53376671; called by muse, varscan2
- PCNT | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV64029636; called by muse, mutect2, varscan2
- PDE6C | c.1420C>G p.Q474E | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV65116871; called by muse, mutect2, varscan2
- PDGFRA | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs751618661, COSV57269720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHF20 | c.2301-1G>T p.X767_splice | Splice Site (SNP) | VAF 185/489 reads (38%) | catalogued as COSV64976328; called by muse, mutect2, varscan2
- PHF20 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV64976333; called by muse, mutect2, varscan2
- PIK3R4 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.604); catalogued as COSV63241539; called by muse, mutect2, varscan2
- PKIA | c.153A>T p.E51D | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61914879; called by muse, mutect2, varscan2
- POLDIP3 | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52809376; called by muse, mutect2, varscan2
- PUM2 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 129/154 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV100163789, COSV57582328; called by muse, mutect2, varscan2
- RAB3C | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV99277302; called by muse, varscan2
- RALGAPA2 | c.3638C>G p.S1213C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV52498285, COSV52501066; called by muse, mutect2, varscan2
- RIOK2 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV51613257, COSV51614577; called by muse, mutect2, varscan2
- SCARB2 | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT tolerated (0.5); PolyPhen benign (0.23); catalogued as COSV53669101; called by muse, mutect2, varscan2
- SEC11C | c.90C>T p.L30= | Splice Region (SNP) | VAF 67/136 reads (49%) | catalogued as rs1315237018, COSV55311692; called by muse, mutect2, varscan2
- SEC23IP | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 63/75 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV64831928; called by muse, mutect2, varscan2
- SIPA1L3 | c.3813C>G p.S1271R | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55916946; called by muse, mutect2, varscan2
- SLC44A5 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 77/141 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV63767532; called by muse, mutect2, varscan2
- SLX4 | c.3661G>T p.A1221S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV53565175; called by muse, mutect2, varscan2
- SOX2 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57621998; called by muse, mutect2, varscan2
- SPAG1 | c.2278G>C p.E760Q | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV52560633, COSV52563651; called by muse, mutect2, varscan2
- SPATA33 | c.209-1G>C p.X70_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as COSV56377734; called by muse, mutect2, varscan2
- STARD7 | c.566G>C p.R189T | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61526092; called by muse, mutect2, varscan2
- SUZ12 | c.1811C>G p.S604C | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV59500956; called by muse, mutect2, varscan2
- SYNE1 | c.3101C>T p.S1034F (on ENST00000367255 / NM_182961.4; = p.S1041F on NM_033071.3) | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs758244463, COSV55013427; called by muse, mutect2, varscan2
- TACC2 | c.3047G>C p.G1016A | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV57759543; called by muse, mutect2, varscan2
- TECTA | c.1000G>C p.D334H | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50726570, COSV99879503; called by muse, mutect2, varscan2
- TMEM87A | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV67747193; called by muse, mutect2, varscan2
- TOPBP1 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV53437346; called by muse, mutect2, varscan2
- TRIOBP | c.821A>C p.E274A | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV60379547; called by muse, mutect2, varscan2
- TRIP13 | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV51320390; called by muse, mutect2, varscan2
- TRPS1 | c.1477G>A p.E493K (on ENST00000220888 / NM_001330599.2; = p.E506K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.027); catalogued as COSV55247153; called by muse, mutect2
- TTN | c.30757G>C p.E10253Q (on ENST00000591111; = p.E9326Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | PolyPhen probably damaging (0.91); catalogued as COSV60139787; called by muse, mutect2, varscan2
- TTN | c.19676C>A p.S6559Y (on ENST00000591111; = p.S5632Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | PolyPhen benign (0); catalogued as COSV60139803; called by muse, mutect2, varscan2
- TUBG2 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 86/270 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs771443380, COSV52217424; called by muse, mutect2, varscan2
- UNC13B | c.4162C>T p.R1388C | Missense Mutation (SNP) | VAF 140/347 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1432832753, COSV65935699; called by muse, mutect2, varscan2
- UTY | c.2793C>G p.F931L | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58870278; called by muse, mutect2, varscan2
- VPS4B | c.1293G>C p.L431F | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV53069870, COSV53070136; called by muse, mutect2, varscan2
- VTI1B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as COSV53619976; called by muse, varscan2
- WDR48 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV56532602; called by muse, mutect2, varscan2
- WNT8A | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64230879; called by muse, mutect2, varscan2
- WSB2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59574378; called by muse, mutect2, varscan2
- XPO1 | c.3109G>C p.E1037Q | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV68946433; called by muse, mutect2, varscan2
- ZFHX4 | c.8650C>A p.Q2884K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.754); catalogued as COSV51444798; called by muse, mutect2, varscan2
- ZFP2 | c.1123A>T p.I375F | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV63726072; called by muse, mutect2
- ZNF257 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV71309326; called by muse, mutect2, varscan2
- ZNF267 | c.1726T>C p.Y576H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV56253799; called by muse, mutect2, varscan2
- ZNF425 | c.738C>G p.F246L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV65201648; called by muse, mutect2, varscan2
- ZNF467 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV57373659; called by muse, mutect2, varscan2
- ZNF83 | c.1535C>G p.S512C | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV56530629; called by muse, mutect2, varscan2
- LGALS9B | c.440_444+3del p.X147_splice | Splice Site (DEL) | VAF 21/65 reads (32%) | called by mutect2, pindel, varscan2
- NAP1L4 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- NCOA6 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 46/122 reads (38%) | called by muse, mutect2, varscan2
- SLC38A2 | c.1023dup p.A342Cfs*14 | Frame Shift Ins (INS) | VAF 39/92 reads (42%) | called by mutect2, pindel, varscan2
- TAOK2 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- THSD4 | c.2037-6_2039del p.X679_splice | Splice Site (DEL) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- TJP2 | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 119/182 reads (65%) | called by muse, mutect2, varscan2
- TTN | c.24217C>T p.Q8073* (on ENST00000591111; = p.Q7146* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- ZNF337 | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- ABCA8 | c.2400C>T p.L800= | Silent (SNP) | VAF 83/236 reads (35%) | catalogued as rs144614574; called by muse, mutect2, varscan2
- ACACA | c.1525A>C p.R509= | Silent (SNP) | VAF 29/165 reads (18%) | called by muse, mutect2, varscan2
- ADCY2 | c.2295C>T p.I765= | Silent (SNP) | VAF 49/260 reads (19%) | catalogued as COSV57874057, COSV57879135; called by muse, mutect2, varscan2
- AP5B1 | c.918A>G p.A306= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- ARFGEF1 | c.3144G>A p.L1048= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV51610904; called by muse, varscan2
- ATP1A1 | c.2175G>A p.L725= | Silent (SNP) | VAF 37/236 reads (16%) | catalogued as COSV55189284, COSV55192072; called by muse, mutect2, varscan2
- ATP2B3 | c.1416C>T p.S472= | Silent (SNP) | VAF 109/130 reads (84%) | catalogued as rs782571754, COSV54851252; called by muse, mutect2, varscan2
- AUTS2 | c.3718C>T p.L1240= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV61386755; called by muse, mutect2, varscan2
- C9orf78 | c.810C>T p.N270= | Silent (SNP) | VAF 64/140 reads (46%) | catalogued as rs147768922, COSV61028841; called by muse, mutect2, varscan2
- CCDC153 | c.498C>G p.L166= | Silent (SNP) | VAF 91/155 reads (59%) | catalogued as COSV59540497; called by muse, mutect2, varscan2
- CCDC87 | c.366G>A p.L122= | Silent (SNP) | VAF 56/128 reads (44%) | catalogued as rs893310467, COSV59579442; called by muse, mutect2, varscan2
- CECR2 | c.300G>C p.L100= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV52843468; called by muse, mutect2, varscan2
- CHST2 | c.537C>T p.F179= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV100536104, COSV58886026; called by muse, mutect2, varscan2
- CUL7 | c.3288C>T p.L1096= | Silent (SNP) | VAF 90/104 reads (87%) | catalogued as COSV54818541; called by muse, mutect2, varscan2
- FAT3 | c.12624G>A p.P4208= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV53128054; called by muse, mutect2, varscan2
- GANAB | c.1791C>G p.P597= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV60465737; called by muse, mutect2, varscan2
- GAS2L2 | c.408G>A p.E136= | Silent (SNP) | VAF 30/352 reads (9%) | called by muse, mutect2
- GRB10 | c.1755C>G p.L585= (on ENST00000398812; = p.L539= on NM_001001549.3) | Silent (SNP) | VAF 104/232 reads (45%) | catalogued as COSV60011825; called by muse, mutect2, varscan2
- GSDME | c.1005C>A p.V335= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as rs1450238958, COSV61652037; called by muse, mutect2, varscan2
- HNRNPUL1 | c.702C>T p.L234= | Silent (SNP) | VAF 116/275 reads (42%) | catalogued as COSV54563461; called by muse, mutect2, varscan2
- HPS5 | c.951G>A p.Q317= (on ENST00000349215 / NM_181507.2; = p.Q203= on NM_007216.4) | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV61687620; called by muse, mutect2, varscan2
- IKZF1 | c.1515C>T p.F505= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV58785082; called by muse, mutect2, varscan2
- ITGA2 | c.1086C>T p.F362= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV56861608; called by muse, mutect2, varscan2
- KLHL32 | c.828C>T p.V276= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV65112485; called by muse, mutect2, varscan2
- MAML1 | c.2946G>T p.G982= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs755578473, COSV52986466; called by muse, mutect2, varscan2
- MKRN1 | c.402C>G p.L134= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs757764783, COSV55437345; called by muse, mutect2, varscan2
- MYLK3 | c.768G>A p.E256= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV67364896; called by muse, mutect2, varscan2
- NRAP | c.1305T>C p.V435= (on ENST00000359988 / NM_001322945.2; = p.V400= on NM_006175.4) | Silent (SNP) | VAF 61/93 reads (66%) | catalogued as rs371038249; called by muse, mutect2, varscan2
- OR4X2 | c.354C>T p.I118= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as COSV56583760; called by muse, mutect2, varscan2
- PCDHGA10 | c.354G>A p.V118= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV53969317; called by muse, mutect2, varscan2
- PNLDC1 | c.1140C>T p.P380= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs545678739, COSV51706123; called by muse, mutect2, varscan2
- SLC7A8 | c.1590G>A p.A530= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as rs563944466, COSV100328504, COSV57554630; called by muse, mutect2, varscan2
- TBC1D19 | c.759C>T p.P253= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV53517930; called by muse, mutect2, varscan2
- TMTC2 | c.36C>T p.L12= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV58272866; called by muse, mutect2, varscan2
- TRAPPC10 | c.717C>T p.F239= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as rs757630711, COSV52378399; called by muse, mutect2
- USP17L2 | c.411C>T p.H137= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs780196046, COSV61556052; called by muse, mutect2, varscan2
- UTY | c.1719G>A p.L573= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV58870310; called by muse, mutect2, varscan2
- VWCE | c.1752G>A p.S584= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs141642839; called by muse, mutect2, varscan2
- WWC3 | c.1830C>T p.R610= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs11544574, COSV66504224; called by muse, mutect2, varscan2
- ZCCHC2 | c.2604C>T p.I868= | Silent (SNP) | VAF 37/174 reads (21%) | catalogued as COSV54038798; called by muse, mutect2, varscan2
- ZNF71 | c.795C>G p.T265= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV100045568, COSV60148541; called by muse, mutect2, varscan2
- PCSK6 | c.1859-15745G>A | Intron (SNP) | VAF 18/57 reads (32%) | catalogued as COSV60168159; called by muse, mutect2, varscan2
